Somatic mutation profile of tumor specimen MP2PRT-PAUYSG-TBP1-A (aliquot MP2PRT-PAUYSG-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUYSG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,482 days).
Specimen MP2PRT-PAUYSG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3e67ac7-0241-406f-836e-fdf0f564b71a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYSG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYSG-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3f7854c-cef2-4d86-8ef4-5dc6cc83117d

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>A p.D835E | Missense Mutation (SNP) | VAF 22/199 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, varscan2
- ADGB | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.158); catalogued as rs1249089131; called by muse, mutect2
- CHRM3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 16/473 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1221241600; called by muse, mutect2
- LAMA5 | c.4745C>T p.A1582V | Missense Mutation (SNP) | VAF 39/630 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs768551124, COSV53353096, COSV53356892; called by muse, mutect2
- LZTR1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 53/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773016962, CM151192, COSV53147760; ClinVar: uncertain significance; called by muse, mutect2
- MTHFR | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs1398982560, COSV64878564; called by muse, mutect2, varscan2
- SDCBP2 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV60590045; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2
- HDAC6 | c.93G>A p.S31= | Splice Region (SNP) | VAF 71/551 reads (13%) | called by muse, mutect2, varscan2
- RETNLB | c.47A>C p.Q16P | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- WWC3 | c.2726C>T p.T909I | Missense Mutation (SNP) | VAF 35/802 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- YY2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 63/862 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2
- ERBB4 | c.1425A>C p.T475= | Silent (SNP) | VAF 11/308 reads (4%) | called by muse, mutect2
- GPR158 | c.672C>T p.H224= | Silent (SNP) | VAF 44/788 reads (6%) | catalogued as COSV66284363; called by muse, mutect2
- ZNF185 | c.762G>A p.A254= | Silent (SNP) | VAF 37/608 reads (6%) | catalogued as rs140454766, COSV59278866; called by muse, mutect2
